Somatic mutation profile of tumor specimen MMRF_2711_1_BM_CD138pos (aliquot MMRF_2711_1_BM_CD138pos_T1_KHS5U_L14834) from MMRF case MMRF_2711, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.0 years (22,262 days).
Specimen MMRF_2711_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a42d358-2754-4bcc-968a-10c83edb409e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2711_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2711_1_PB_WBC_C2_KHS5U_L14842; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac74d918-1d76-4df6-946f-e5ff718a8679

The open-access MAF lists 82 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 16, Intron 11, Silent 9, 5'UTR 3, Nonsense Mutation 2, 5'Flank 2, Splice Site 1, RNA 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.6511G>A p.D2171N (on ENST00000614293; = p.D2141N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/393 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs755962897; called by muse, mutect2, varscan2
- ACTB | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV59316533, COSV59317010, COSV59320272; called by muse, mutect2, varscan2
- ADGB | c.3880G>A p.E1294K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as rs896180025; called by muse, mutect2, varscan2
- DNAH7 | c.8044G>A p.A2682T | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199807387, COSV100413216; called by muse, mutect2, varscan2
- IGHV2-70 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 142/185 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370286145; called by muse, varscan2
- IGLV1-47 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs763189999; called by muse, varscan2
- IGLV3-1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 142/146 reads (97%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs754927085; called by muse, mutect2, varscan2
- LPP | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV57099709; called by muse, mutect2, varscan2
- MEP1B | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52496294; called by muse, mutect2, varscan2
- PPP1R16B | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs909247136, COSV100239978, COSV55374467; called by muse, mutect2, varscan2
- PRICKLE2 | c.2390G>A p.R797Q (on ENST00000295902; = p.R741Q on NM_198859.4) | Missense Mutation (SNP) | VAF 93/178 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.432); catalogued as rs202197921; called by muse, mutect2, varscan2
- PTPN5 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 124/239 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.898); catalogued as rs890447148, COSV60031473; called by muse, mutect2, varscan2
- RP1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 81/148 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs754949406, COSV55124785; called by muse, mutect2, varscan2
- SPANXN4 | c.65G>T p.R22I | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1569428455; called by muse, mutect2, varscan2
- ADAM30 | c.1381G>T p.G461* | Nonsense Mutation (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- CADPS | c.3218C>A p.A1073D | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ESYT2 | c.1969C>G p.L657V (on ENST00000613624; = p.L581V on NM_020728.3) | Missense Mutation (SNP) | VAF 66/325 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ETS2 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, varscan2
- FLT1 | c.1984T>C p.Y662H | Missense Mutation (SNP) | VAF 71/73 reads (97%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPAM | c.2122-8A>C | Splice Region (SNP) | VAF 98/182 reads (54%) | called by muse, mutect2, varscan2
- HCN4 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCRTR2 | c.373T>C p.S125P | Missense Mutation (SNP) | VAF 105/346 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGHV1-69 | c.92A>T p.K31M | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); called by mutect2, varscan2
- IGHV2-70D | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.108); called by muse, varscan2
- IGKV1D-42 | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 132/278 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IL17RE | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- OGG1 | c.1082C>G p.S361C | Missense Mutation (SNP) | VAF 116/261 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- OR5F1 | c.601A>T p.I201F | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- OR5M1 | c.703C>A p.H235N | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PBX1 | c.1127A>C p.H376P | Missense Mutation (SNP) | VAF 136/496 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPN18 | c.924+2T>C p.X308_splice | Splice Site (SNP) | VAF 93/211 reads (44%) | called by muse, mutect2, varscan2
- RASIP1 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 96/166 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RBM39 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- RFTN1 | c.482T>G p.V161G | Missense Mutation (SNP) | VAF 82/149 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TBL1XR1 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2
- TMPRSS13 | c.1682G>T p.R561I | Missense Mutation (SNP) | VAF 112/291 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TMTC3 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TRPV2 | c.800_801del p.T267Kfs*4 | Frame Shift Del (DEL) | VAF 130/299 reads (43%) | called by mutect2, varscan2
- UBR3 | c.1794T>G p.Y598* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- ZNF717 | c.478A>T p.N160Y | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BRPF1 | c.24G>A p.K8= | Silent (SNP) | VAF 181/391 reads (46%) | catalogued as COSV100121000, COSV57406924; called by muse, mutect2, varscan2
- BRPF1 | c.267G>A p.V89= | Silent (SNP) | VAF 109/220 reads (50%) | called by muse, mutect2, varscan2
- CD19 | c.168C>T p.S56= | Silent (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- IL16 | c.2664G>A p.G888= (on ENST00000302987 / NM_172217.5; = p.G187= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 149/468 reads (32%) | catalogued as rs753315799; called by muse, mutect2, varscan2
- MTRF1 | c.201G>A p.K67= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- OR6M1 | c.174C>T p.Y58= | Silent (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- PKDREJ | c.246C>T p.G82= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1379635558; called by muse, mutect2, varscan2
- TBX18 | c.1380G>T p.V460= | Silent (SNP) | VAF 103/270 reads (38%) | catalogued as COSV63737591; called by muse, mutect2, varscan2
- ZNF618 | c.783C>T p.C261= (on ENST00000374126 / NM_001318042.2; = p.C249= on NM_133374.2) | Silent (SNP) | VAF 74/295 reads (25%) | catalogued as rs765868140; called by muse, mutect2, varscan2
- ATG16L1 | c.*863C>T | 3'UTR (SNP) | VAF 103/223 reads (46%) | called by muse, mutect2, varscan2
- ATP2C1 | c.*1461C>G | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- EXTL2 | c.*744A>G | 3'UTR (SNP) | VAF 56/105 reads (53%) | catalogued as rs1442746468; called by muse, mutect2, varscan2
- GRIA2 | c.1267-74G>T | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102344C>T | Intron (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- IL17RE | c.132+161G>A | Intron (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- KIAA0895 | c.867+1231_867+1234del | Intron (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- MCF2L | c.459+1273C>T | Intron (SNP) | VAF 326/347 reads (94%) | catalogued as rs1472086557; called by muse, mutect2, varscan2
- NSFL1C | c.*400C>G | 3'UTR (SNP) | VAF 48/97 reads (49%) | called by muse, mutect2, varscan2
- NUDT13 | c.*603_*645del | 3'UTR (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- PDE4D | c.*46T>C | 3'UTR (SNP) | VAF 51/203 reads (25%) | catalogued as COSV72351114; called by muse, mutect2, varscan2
- PHF21B | c.*1232_*1234del | 3'UTR (DEL) | VAF 122/263 reads (46%) | called by mutect2, pindel, varscan2
- POLD4 | c.98-79A>C | Intron (SNP) | VAF 52/111 reads (47%) | called by muse, mutect2, varscan2
- PRR15 | c.-103G>A | 5'UTR (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- RASL11B | c.199+125C>G | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- RBM15B | c.*3386C>T | 3'UTR (SNP) | VAF 105/243 reads (43%) | catalogued as rs1228074653, COSV60041377; called by muse, varscan2
- RNF157 | c.89-13373G>A | Intron (SNP) | VAF 53/97 reads (55%) | catalogued as rs1299544962; called by muse, mutect2, varscan2
- RNF207 | c.324+438A>G | Intron (SNP) | VAF 51/90 reads (57%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1138A>T | RNA (SNP) | VAF 22/102 reads (22%) | called by muse, varscan2
- SCNN1D | c.-1057G>A | 5'UTR (SNP) | VAF 33/54 reads (61%) | catalogued as rs566600624; called by muse, mutect2, varscan2
- SEZ6L | c.*2056T>G | 3'UTR (SNP) | VAF 33/60 reads (55%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.*3725A>T | 3'UTR (SNP) | VAF 38/55 reads (69%) | called by muse, mutect2, varscan2
- SMAD7 | c.-92C>T | 5'UTR (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- SMOC2 | c.*322G>T | 3'UTR (SNP) | VAF 125/175 reads (71%) | called by muse, mutect2, varscan2
- TBC1D2B | c.1582-107C>T | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2
- TMED8 | c.*376C>T | 3'UTR (SNP) | VAF 52/117 reads (44%) | catalogued as rs560680542; called by muse, mutect2, varscan2
- TMEM98 | c.*566A>G | 3'UTR (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- TRABD2A | chr2:84881122 del CGCGGGG | 5'Flank (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- TTLL3 | c.2126-380C>A | Intron (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- UTP25 | c.*100C>A | 3'UTR (SNP) | VAF 55/145 reads (38%) | called by muse, mutect2, varscan2
- WDR76 | c.*1905dup | 3'UTR (INS) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- ZFP64 | c.*516_*517del | 3'UTR (DEL) | VAF 26/39 reads (67%) | catalogued as rs745333836; called by mutect2, pindel, varscan2
- ZNF578 | chr19:52451363 G>A | 5'Flank (SNP) | VAF 45/140 reads (32%) | catalogued as COSV56515785; called by muse, mutect2, varscan2
